Somatic mutation profile of tumor specimen TARGET-10-PAPHYV-09A (aliquot TARGET-10-PAPHYV-09A-01D) from TARGET case TARGET-10-PAPHYV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (987 days).
Specimen TARGET-10-PAPHYV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf066eb8-2756-428f-98b0-4ad2a99b2abc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPHYV-14A (Bone Marrow Normal), aliquot TARGET-10-PAPHYV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/650a7b7b-fa5f-4ed8-b02c-7625eec69f2c

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCORL1 | c.3268C>T p.R1090* | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as COSV54389244; called by muse, mutect2, varscan2
- ERBB3 | c.3353G>A p.R1118Q | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.194); catalogued as rs201958747, COSV57247934; called by muse, mutect2, varscan2
- LRP1 | c.2594G>A p.R865H | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs547779616; called by muse, mutect2, varscan2
- PCDH17 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV64971777, COSV64972890; called by muse, mutect2, varscan2
- FAM135B | c.542G>T p.S181I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SIGLEC6 | c.141C>T p.V47= | Silent (SNP) | VAF 28/94 reads (30%) | called by muse, mutect2, varscan2
- UNC80 | c.1644C>T p.S548= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as rs1302639981; called by muse, mutect2, varscan2
- ZNF57 | chr19:2896914 A>C | 5'Flank (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
